Gene-level copy-number profile of tumor specimen ALCH-B35Z-TTP1-A from ALCHEMIST case ALCH-B35Z, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 76.8 years (28,052 days).
Specimen ALCH-B35Z-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e259dbe7-e93a-44de-939e-c22109a8ceb6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B35Z-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,746 have no estimate.
https://portal.gdc.cancer.gov/files/37c89c9c-9517-4efa-b733-e751af6c5c0d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 707; copy number 1: 32; copy number 2: 10,026; copy number 3: 12,737; copy number 4: 20,225; copy number 5: 6,568; copy number 6: 6,776; copy number 7: 1,392; copy number 8: 17; copy number 9: 363; copy number 10: 8; copy number 12: 2; copy number 14: 1; copy number 19: 23.

Homozygous deletions (total copy number 0; autosomes only): 195 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,838,125–12,841,357, 1 gene: PRAMEF30P.
- chr1:12,857,086–12,861,909, 1 gene (within-gene range 0–2): PRAMEF2.
- chr1:161,617,992–161,631,963, 2 genes (within-gene range 0–1): RPS23P9, FCGR3B.
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr8:8,116,745–8,116,949, 1 gene: SNRPCP17.
- chr8:12,362,019–12,400,366, 4 genes: FAM66A, AC087203.1, AC087203.2, DEFB109A.
- chr9:19,507,452–26,796,304, 96 genes (broad region; genes not listed).
- chr9:39,734,670–39,741,193, 2 genes: RAB28P1, RBPJP5.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–2): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–2): IGHV3-43.
- chr21:13,038,160–16,645,467, 82 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 397 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,036,321–151,146,664, 8 genes, copy number 10: BNIPL, C1orf56, CDC42SE1, MLLT11, GABPB2, RPS29P29, AL592424.1, SEMA6C.
- chr8:38,099,471–39,580,134, 42 genes, copy number 9–19: AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1.
- chr17:15,565,483–16,684,227, 57 genes, copy number 9–12: CDRT1, AC005324.2, SNORA74, AC005838.1, TRIM16, AC005324.4, ZNF29P, ZNF286A, AC005324.3, UBE2SP1, TBC1D26, TBC1D26-AS1, AC005324.5, AC005324.1, CDRT15P2, ZSWIM5P1, RNA5SP436, IL6STP1, MEIS3P1, AC015922.2, AC015922.3, AC015922.1, LINC02087, SPECC1P1, ADORA2B, ZSWIM7, TTC19, AC002553.2, NCOR1, AC002553.1, RPLP1P11, RPL22P21, RNU6-314P, RNU6-862P, RN7SL442P, PIGL, MIR1288, CENPV, UBB, AC093484.3, FTLP12, AC093484.2, TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A, ZNF287, AC127540.1, SRSF6P2, ZNF624, AC098850.2, NEK4P2, RNASEH1P2.
- chr17:16,893,198–22,706,703, 289 genes, copy number 9 (broad region; genes not listed).
- chr21:8,603,547–8,603,984, 1 gene, copy number 12: RPSAP68.

Autosomal genes at a single copy (total copy number 1): 24. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
